CGCI case HTMCP-02-31-01244 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9a6070f5-6a47-483f-a804-bf5ee83f6114

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 182 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Non-small cell carcinoma: ICD-O-3 morphology code: 8046/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.1 years (25,233 days); Year of diagnosis: 2000; Method of diagnosis: Imaging; AJCC staging edition: 5th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 151 days.
   Pathology details: Lymph nodes tested: 4.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 151 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day 0: CD4 count: 457; Haart treatment indicator: Yes; HIV viral load: 210.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: AIDS risk factors: Candidiasis.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 5.5.

Biospecimens (2 samples)
- Sample HTMCP-02-31-01244-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-31-01244-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Non-Small Cell Lung Cancer (NOS); Tumor status: Tumor free; Tobacco smoking age started: 14; Cause of death: Non-Cancer Related; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Prior aids conditions: Candidiasis, esophageal.
- Primary pathology: Lymph nodes examined: Yes; Method initial path diagnosis: Other method, specify:; Days from index date to tumor sample procurement: 31; Method initial path diagnosis other: Fiberoptic Bronchoscope; Other pos node location: Peribronchial.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-31-01244-01A-01E-18796:
- % tumour top: 85
- % tumour bottom: 85

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-31-01244-01A-01S-18796:
- % tumour top: 85
- % tumour bottom: 85
